Gene-level copy-number profile of tumor specimen TCGA-AA-A02O-01A from TCGA case TCGA-AA-A02O, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage II; Age at diagnosis: 82.9 years (30,288 days).
Specimen TCGA-AA-A02O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.18abcd4a-cfa6-403e-9d9b-96c2279476d8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A02O-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b636fe0-e865-4e48-8d26-9fe63a558900

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 621; copy number 2: 42,945; copy number 3: 15,358; copy number 5: 440; copy number 6: 131; copy number 7: 33; copy number 8: 256; copy number 13: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A02O-01A-21D-A080-01): tumor purity 0.8, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,573,767–6,748,969, 4 genes: AC007223.1, AC007012.2, AC007012.1, RNU7-99P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 889 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:22,671,433–30,186,475, 181 genes, copy number 5–8 (broad region; genes not listed).
- chr17:30,551,193–40,061,215, 392 genes, copy number 5–13 (broad region; genes not listed).
- chr17:48,646,923–49,176,840, 33 genes, copy number 7 (within-gene range 2–7): LINC02086, AC091179.2, RPL9P28, PRAC1, PRAC2, AC091179.3, AC091179.4, MIR3185, HOXB13, AC091179.1, TTLL6, RN7SL125P, CALCOCO2, SUMO2P17, AC068531.1, AC068531.2, ATP5MC1, AC091133.6, UBE2Z, SNF8, AC091133.1, RNU1-42P, AC091133.2, GIP, AC091133.3, IGF2BP1, AC091133.4, Metazoa_SRP, RNU6-826P, AC091133.5, B4GALNT2P1, B4GALNT2, AC069454.1.
- chr17:58,148,449–64,662,307, 234 genes, copy number 6–8 (broad region; genes not listed).
- chr17:65,457,541–67,984,378, 49 genes, copy number 8 (within-gene range 2–8): LINC02563, AXIN2, AC004805.1, CEP112, AC004805.3, AC004805.2, PSMD7P1, APOH, RNA5SP444, AC009452.1, PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3.

Autosomal genes at a single copy (total copy number 1): 621. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
